Somatic mutation profile of tumor specimen TCGA-04-1371-01A (aliquot TCGA-04-1371-01A-01D-0516-08) from TCGA case TCGA-04-1371, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 58.2 years (21,243 days).
Specimen TCGA-04-1371-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc8d2a5f-6974-4c9d-b6ec-a704621a3a1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1371-11A (Solid Tissue Normal), aliquot TCGA-04-1371-11A-01W-0492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bba9dfc5-f31d-4dfa-abff-4306bcd5a5fb

The open-access MAF lists 30 somatic variants for this specimen: 18 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 10, Splice Region 1, Intron 1, Nonsense Mutation 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD6 | c.519A>T p.A173= | Splice Region (SNP) | VAF 6/56 reads (11%) | catalogued as COSV60238167; called by mutect2, varscan2
- C5AR2 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.063); catalogued as rs759726681, COSV57256195; called by muse, mutect2, varscan2
- FBN2 | c.5467G>T p.V1823L | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.287); catalogued as COSV52493323; called by muse, mutect2, varscan2
- FLT3 | c.2957C>T p.P986L | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as rs587778369, COSV54047766, COSV54049596; ClinVar: not provided; called by muse, mutect2, varscan2
- HARBI1 | c.435G>A p.M145I | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs771670880; called by muse, mutect2
- NODAL | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV54661453; called by muse, mutect2, varscan2
- SSH2 | c.2005C>T p.R669* | Nonsense Mutation (SNP) | VAF 8/112 reads (7%) | catalogued as COSV52175155; called by muse, mutect2
- TTC39B | c.1520G>A p.G507E | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99896347; called by muse, mutect2, varscan2
- API5 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- DPM1 | c.488_489del p.I163Nfs*19 | Frame Shift Del (DEL) | VAF 30/300 reads (10%) | called by mutect2, pindel, varscan2
- NFKBIZ | c.1636G>C p.E546Q | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCD3 | c.1274C>A p.P425H | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PPIL2 | c.190C>A p.L64M | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.14); called by muse, mutect2
- SAA1 | c.20T>G p.L7R | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- SLC45A3 | c.274C>A p.L92M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.92); called by muse, varscan2
- SORT1 | c.543G>T p.K181N | Missense Mutation (SNP) | VAF 13/179 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- SP100 | c.185T>G p.V62G | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZP2 | c.577A>G p.R193G | Missense Mutation (SNP) | VAF 52/349 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHRM1 | c.1236C>T p.T412= | Silent (SNP) | VAF 9/151 reads (6%) | called by muse, mutect2
- CLDND2 | c.503G>A p.*168= | Silent (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- GRHL2 | c.390C>T p.H130= | Silent (SNP) | VAF 57/469 reads (12%) | catalogued as COSV52551474; called by muse, mutect2, varscan2
- MLST8 | c.954G>A p.L318= | Silent (SNP) | VAF 23/25 reads (92%) | catalogued as rs368659999; called by muse, mutect2, varscan2
- PHTF2 | c.943C>T p.L315= (on ENST00000248550 / NM_001366089.1; = p.L277= on NM_020432.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 9/202 reads (4%) | called by muse, mutect2
- USH2A | c.7893G>A p.E2631= | Silent (SNP) | VAF 34/167 reads (20%) | called by muse, mutect2, varscan2
- VSTM4 | c.171G>A p.L57= | Silent (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- WWC3 | c.705T>C p.N235= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs951857456, COSV66501663; called by muse, varscan2
- ZNF479 | c.1362C>T p.D454= | Silent (SNP) | VAF 14/398 reads (4%) | called by muse, mutect2
- ZRANB2 | c.735C>T p.S245= | Silent (SNP) | VAF 24/257 reads (9%) | catalogued as rs752135414; called by muse, mutect2
- LRP1 | c.841+3503C>T | Intron (SNP) | VAF 7/15 reads (47%) | catalogued as rs747699937; called by muse, mutect2, varscan2
- MIR892A | n.61C>T | RNA (SNP) | VAF 82/238 reads (34%) | called by muse, mutect2, varscan2
